FM case AD15747 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Transitional Cell Papillomas and Carcinomas; Primary site: Bladder.
https://portal.gdc.cancer.gov/cases/283e1705-4dc5-4f2f-aac0-8057a989059a

Male, 63.6 years: Urothelial carcinoma, NOS (ICD-O-3 8120/3) of the bladder; primary biopsied or resected from the bladder. Tumor nuclei on the sequenced sample's slide: 30% (pathologist estimate recorded by GDC). Sample type: Primary Tumor.
